Somatic mutation profile of tumor specimen 0DENCK from CCDI case PBBPNR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (758 days).
Specimen 0DENCK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c5d8245-82b0-4a0a-94c0-da04f0d6dad9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DENBV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db27261e-2f50-4234-a2f4-198c959f7428

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2B | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.955); catalogued as rs748075089, COSV101663194, COSV74205288; called by muse, varscan2
- HUWE1 | c.2185G>C p.D729H | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, varscan2
- PDRG1 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, varscan2
- GH1 | c.11-23G>A | Intron (SNP) | VAF 20/98 reads (20%) | catalogued as rs766859584; called by muse, varscan2
- GH1 | c.11-24T>C | Intron (SNP) | VAF 18/96 reads (19%) | catalogued as rs755049792; called by muse, varscan2
